Somatic mutation profile of tumor specimen TCGA-2H-A9GK-01A (aliquot TCGA-2H-A9GK-01A-11D-A37C-09) from TCGA case TCGA-2H-A9GK, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 44.0 years (16,067 days).
Specimen TCGA-2H-A9GK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fdae3b2-46f3-4324-81ad-aefa6950c766.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2H-A9GK-11A (Solid Tissue Normal), aliquot TCGA-2H-A9GK-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c396e686-4d1a-43cb-a5b4-34b39957ce99

The open-access MAF lists 198 somatic variants for this specimen: 139 protein-altering or splice-affecting, 54 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 54, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 3, Intron 2, RNA 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAH | c.1199G>C p.R400T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs199475658, CD962118, CM034748, CM056669; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1292A>C p.K431T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen benign (0.241); catalogued as COSV65046911, COSV65048763; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.1435T>G p.F479V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63666681; called by muse, mutect2, varscan2
- ADARB2 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs200545586; called by muse, mutect2, varscan2
- ADCY1 | c.2105A>T p.K702M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV52041523; called by muse, mutect2, varscan2
- AKAP6 | c.4882C>G p.L1628V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55224845; called by mutect2, varscan2
- ANKLE2 | c.2297G>C p.R766T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs1367285955, COSV61710777; called by muse, mutect2, varscan2
- ANKRD13A | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763901109, COSV55675252, COSV55679096; called by muse, mutect2, varscan2
- ARFGEF2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs778834589, COSV64211088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP19 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.843); catalogued as rs372891158; called by muse, mutect2, varscan2
- ARHGAP28 | c.1307T>C p.L436P (on ENST00000383472 / NM_001366230.1; = p.L277P on NM_001010000.3) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1214308156, COSV51632708, COSV51641871; called by muse, mutect2, varscan2
- AXL | c.2398C>T p.R800W (on ENST00000301178 / NM_021913.5; = p.R791W on NM_001699.6) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036430672, COSV56563418, COSV56565829; called by muse, mutect2, varscan2
- BAMBI | c.668A>G p.E223G | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs764485833; called by muse, mutect2, varscan2
- CABIN1 | c.3373G>A p.V1125I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs148592192; called by muse, mutect2, varscan2
- CARM1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV59000186; called by muse, mutect2, varscan2
- CCL8 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV67013920; called by muse, mutect2, varscan2
- CDH12 | c.1389A>C p.K463N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66393702, COSV66402702; called by muse, mutect2, varscan2
- CHRM2 | c.958T>C p.S320P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV57775026; called by muse, mutect2, varscan2
- COL7A1 | c.4652G>A p.G1551E | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467683481; called by muse, mutect2, varscan2
- CR1 | c.2365C>G p.R789G | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV65460285; called by muse, mutect2, varscan2
- CSMD3 | c.714A>T p.E238D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.965); catalogued as COSV52209949, COSV52211199; called by muse, varscan2
- CYLC1 | c.1568A>C p.E523A | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as COSV61413144; called by muse, mutect2, varscan2
- DSE | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as COSV59064810; called by muse, mutect2, varscan2
- EML2 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs767071113, COSV55601187; called by muse, mutect2, varscan2
- EVX2 | c.5T>C p.M2T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs770227373; called by muse, mutect2, varscan2
- EXOC3L2 | c.2174C>G p.A725G | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV52973168; called by muse, mutect2
- F11 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as rs373212439; called by muse, mutect2, varscan2
- FBN2 | c.3701C>T p.T1234M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368105987; ClinVar: uncertain significance; called by muse, varscan2
- FBXO10 | c.2651G>A p.R884Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs867197833; called by muse, mutect2, varscan2
- FLG | c.3643A>C p.S1215R | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV100910503, COSV64238953, COSV64251096; called by muse, mutect2, varscan2
- FRAS1 | c.11516G>A p.R3839Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375219965; called by muse, varscan2
- GLRB | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52418286; called by muse, mutect2, varscan2
- GRXCR1 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs766194495, COSV67670732; called by muse, mutect2, varscan2
- H4C2 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1296621230, COSV55138254, COSV99774715, COSV99774982; called by muse, mutect2
- HSPG2 | c.4798G>A p.G1600R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs201665758, COSV101020404; called by muse, mutect2, varscan2
- IL21 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs763638879, COSV52646033; called by mutect2, varscan2
- IRX4 | c.322T>G p.S108A | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99182583; called by muse, mutect2, varscan2
- MROH2B | c.4487A>C p.K1496T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV101270987; called by muse, mutect2, varscan2
- NRG1 | c.288A>C p.E96D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764015527; called by muse, mutect2, varscan2
- OBSCN | c.13969C>A p.H4657N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as rs968774392; called by muse, mutect2, varscan2
- OR10H2 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.694); catalogued as COSV59945928; called by muse, mutect2, varscan2
- OR4A16 | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV59045388; called by muse, mutect2, varscan2
- OR8I2 | c.311T>C p.F104S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1286826012; called by muse, mutect2, varscan2
- PCDHA11 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as rs1554164920; called by muse, mutect2, varscan2
- PCNT | c.4621G>A p.D1541N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs751855202; called by muse, mutect2, varscan2
- PELI3 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.107); catalogued as rs770922679, COSV57856585; called by muse, mutect2, varscan2
- PLCG1 | c.2708C>T p.S903L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs200504048, COSV54814364; called by muse, mutect2, varscan2
- PLD6 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs201208806; called by muse, mutect2, varscan2
- PLXNA4 | c.4259A>G p.K1420R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.656); catalogued as COSV58135568; called by muse, mutect2, varscan2
- PRKCQ | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1248923790; called by muse, mutect2, varscan2
- RHOA | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69043041; called by muse, mutect2
- SCG2 | c.1195T>G p.L399V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV59538910, COSV59540439; called by muse, mutect2, varscan2
- SIGLEC1 | c.3512C>T p.A1171V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs145108646; called by muse, mutect2, varscan2
- SIRPG | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs200001337, COSV53806610; called by muse, mutect2, varscan2
- SLC5A8 | c.1363T>C p.W455R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766865298; called by mutect2, varscan2
- SLIT2 | c.4013A>G p.K1338R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1359336322, COSV56585292; called by muse, mutect2, varscan2
- SMARCC2 | c.3457A>G p.M1153V | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.267); catalogued as rs1238127922; called by muse, mutect2, varscan2
- TAF1L | c.513A>C p.Q171H | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.308); catalogued as COSV54270250; called by muse, mutect2, varscan2
- TBC1D17 | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV99680513; called by muse, mutect2
- TBC1D9 | c.2364G>C p.L788F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as rs1200494557; called by muse, mutect2, varscan2
- TLN2 | c.2634+1G>C p.X878_splice | Splice Site (SNP) | VAF 15/49 reads (31%) | catalogued as COSV60894749; called by muse, mutect2, varscan2
- TRIM3 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1227828415, COSV100624277; called by muse, mutect2, varscan2
- TRIML2 | c.650A>C p.K217T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV58719574; called by muse, mutect2, varscan2
- TRPM3 | c.1268A>G p.K423R (on ENST00000357533 / NM_001366142.2; = p.K268R on NM_020952.6) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs1387201803; called by muse, mutect2, varscan2
- TWIST1 | c.472T>G p.F158V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM013612; called by muse, mutect2, varscan2
- WDR5B | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV58072457; called by muse, mutect2, varscan2
- WNK2 | c.4804G>A p.V1602M (on ENST00000297954 / NM_001282394.1; = p.V1565M on NM_006648.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs1214986248; called by muse, mutect2
- ZNF606 | c.495A>G p.I165M | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1285875558; called by muse, mutect2
- ABCB4 | c.2598T>G p.I866M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ADAMTS19 | c.1236A>C p.E412D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ALDH1L1 | c.470A>G p.D157G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- ANGPT1 | c.1103A>G p.Q368R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ATP5F1C | c.414_415del p.G139Hfs*4 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by pindel, varscan2
- ATRNL1 | c.2581A>T p.N861Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ATRNL1 | c.2888A>C p.D963A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- BRINP1 | c.548A>T p.H183L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CATSPERE | c.115-2A>G p.X39_splice | Splice Site (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- CCDC33 | c.1497G>C p.M499I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLSTN2 | c.2089T>G p.C697G | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNTN4 | c.1388G>A p.R463K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.029); called by mutect2, varscan2
- COL22A1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRB1 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.3154A>G p.K1052E (on ENST00000297405 / NM_001363185.1; = p.K948E on NM_052900.3) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUBN | c.6944G>C p.R2315T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DCHS1 | c.6724G>T p.E2242* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- DDIAS | c.529_541del p.V177Sfs*27 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- DDX42 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DLG5 | c.2946_2978del p.Q983_P993del | In Frame Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel
- DST | c.7679A>T p.E2560V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- EFTUD2 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT3 | c.11999A>C p.N4000T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- GABRA2 | c.320C>G p.P107R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNRH1 | c.241A>G p.S81G | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- GPR150 | c.1095G>C p.Q365H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- GRIA1 | c.295T>G p.S99A | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRIA4 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HSD17B13 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- HUWE1 | c.11959G>A p.D3987N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGKV3D-11 | c.308T>G p.F103C | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IL11RA | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- INTS2 | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- MAGEE2 | c.30C>G p.H10Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAST2 | c.2071T>G p.Y691D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MBIP | c.791-2A>T p.X264_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- MEX3B | c.1490C>G p.S497C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MROH9 | c.230C>A p.P77Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MS4A14 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAV3 | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NELL2 | c.649T>G p.F217V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- NME8 | c.870A>T p.E290D | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- NPHS1 | c.3354G>C p.Q1118H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- OR10X1 | c.33A>C p.Q11H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); called by mutect2, varscan2
- OR2L2 | c.307T>C p.F103L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PASD1 | c.469T>G p.F157V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- POTED | c.179A>C p.K60T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PPHLN1 | c.71del p.S24Mfs*7 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- PWP1 | c.852G>C p.W284C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM12B | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); called by mutect2, varscan2
- RESF1 | c.2041A>G p.K681E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, varscan2
- RPTOR | c.2011G>T p.V671L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SIN3B | c.2612C>G p.T871S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TENM3 | c.1134A>C p.Q378H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- TET3 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- TEX13A | c.211A>G p.S71G | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TFR2 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- TRGV2 | c.286T>G p.L96V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- UNC50 | c.51G>C p.L17F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- UNC5D | c.1979T>A p.L660H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VCPIP1 | c.2240C>A p.S747Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- VIPAS39 | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- VWCE | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZIC1 | c.957A>C p.L319F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF185 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ZNF215 | c.852G>T p.L284F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF570 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2
- ZNF585A | c.1436C>G p.S479* (on ENST00000292841 / NM_001288800.2; = p.S424* on NM_152655.3) | Nonsense Mutation (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- ZNF677 | c.294A>C p.E98D | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF84 | c.2000A>C p.K667T | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ABCA13 | c.12873A>G p.Q4291= | Silent (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- ACSM2A | c.489C>T p.V163= (on ENST00000219054; = p.V84= on NM_001308169.2) | Silent (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- AKAP3 | c.1314C>T p.P438= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- ALCAM | c.33G>A p.L11= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- ANK2 | c.5145A>G p.K1715= | Silent (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- ASPM | c.3858C>G p.L1286= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- ASXL3 | c.1167T>C p.T389= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- C21orf58 | c.519C>G p.A173= | Silent (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- CACTIN | c.225G>A p.P75= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs376574412; called by muse, mutect2, varscan2
- CLDN17 | c.102T>C p.A34= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV54522992; called by muse, mutect2, varscan2
- CLEC6A | c.405T>C p.S135= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV101165725; called by muse, mutect2, varscan2
- COL5A1 | c.4656C>A p.G1552= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- CRNN | c.918C>T p.S306= | Silent (SNP) | VAF 40/116 reads (34%) | called by muse, varscan2
- CRTAC1 | c.684G>T p.V228= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- CUL9 | c.3402C>T p.I1134= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as rs1190276373; called by muse, mutect2, varscan2
- DENND4A | c.4458C>T p.I1486= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1289121297; called by muse, mutect2
- DSG1 | c.2448G>A p.S816= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs772943379; called by muse, mutect2, varscan2
- GJB5 | c.240G>A p.Q80= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- GTPBP2 | c.522T>C p.R174= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- HRH2 | c.289C>T p.L97= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- HRNR | c.1806T>A p.S602= | Silent (SNP) | VAF 42/119 reads (35%) | called by muse, mutect2, varscan2
- KIF13B | c.1239G>A p.E413= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- KMO | c.1206T>G p.T402= | Silent (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- LRP1B | c.9891T>C p.T3297= | Silent (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.3571T>C p.L1191= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- MAGEA10 | c.483G>T p.L161= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- MAOA | c.372C>T p.Y124= | Silent (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- MNDA | c.610A>C p.R204= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV63741058; called by muse, mutect2, varscan2
- MOV10 | c.273G>A p.R91= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- MX2 | c.108C>T p.F36= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs766937760, COSV58094843; called by muse, mutect2, varscan2
- NALCN | c.2352T>G p.T784= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- NECAB1 | c.331C>T p.L111= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV70238794; called by muse, mutect2, varscan2
- NOX4 | c.996A>G p.K332= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV99630231; called by muse, mutect2, varscan2
- OTOR | c.354T>C p.V118= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV55722621; called by muse, mutect2, varscan2
- PCDH17 | c.3117A>G p.P1039= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- PDE4B | c.148T>C p.L50= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs757516988, COSV58480420; called by mutect2, varscan2
- PIK3C2B | c.1605C>A p.S535= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100916024; called by muse, mutect2, varscan2
- PLCXD1 | c.159C>T p.N53= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- PLPPR4 | c.1980T>G p.T660= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1280247668, COSV64564235; called by muse, mutect2, varscan2
- RIMS2 | c.1342T>C p.L448= (on ENST00000666250 / NM_001348490.2; = p.L256= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV51669105, COSV51676746; called by muse, mutect2, varscan2
- SDK1 | c.672T>G p.T224= | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- SLC22A6 | c.33G>A p.G11= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100842937; called by muse, mutect2, varscan2
- SLC37A2 | c.1092T>A p.T364= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- SLC6A3 | c.606G>A p.S202= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs376554288, COSV99548678; called by muse, mutect2, varscan2
- SPTA1 | c.6804G>A p.V2268= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs764467830; called by muse, mutect2, varscan2
- TBC1D26 | c.585C>A p.A195= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- TENM3 | c.414G>T p.G138= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs761052824; called by muse, mutect2, varscan2
- TMSB15A | c.87T>G p.L29= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- TNN | c.2838C>T p.G946= | Silent (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- TRIM32 | c.492G>A p.Q164= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- TRIM58 | c.1372T>C p.L458= | Silent (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- ZFP30 | c.1311C>A p.P437= | Silent (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- ZNF208 | c.2424A>G p.E808= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV68104862; called by muse, mutect2, varscan2
- ZNF781 | c.120G>A p.K40= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- C7orf66 | n.201T>C | RNA (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- MIR509-3 | n.47T>C | RNA (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- OR51F2 | c.-8G>C | 5'UTR (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- PCDH15 | c.91+56240A>T | Intron (SNP) | VAF 11/42 reads (26%) | called by muse, varscan2
- PDE4B | c.635-80C>T | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as rs1418716244, COSV58482067; called by muse, mutect2, varscan2
